Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3580, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3580-01A (Primary Tumor).

Diagnosis/diagnoses:

1. Excised live tissue shows established fine nodular cirrhosis and slight fatty degeneration of the hepatic cells. This finding indicates first and foremost nutrition or ethyl-related toxic damage to the parenchyma of the liver.
2. Resected colon with a polypoid, moderately differentiated adenocarcinoma of the colorectal type measuring a maximum of 6 cm in diameter, with infiltration of the tunica submucosa. Tumor-free local lymph nodes. Tumor-free colon resection margins. In addition, two tubular colon mucosa adenomas with low-grade and high-grade dysplasia (synonym: low-grade and high-grade intraepithelial neoplasia).

Stage of tumor: pT1 pN0 (0/22) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file 366d5f5c-9309-47a9-aa57-9eba834c7624 (TCGA-AG-3580.EA12A0D5-102D-47C4-88CE-AF8F2E176FCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).